HCMI case HCM-BROD-0782-C71 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c902d2a4-d473-498e-a235-c66960ffdefe

Demographics
Sex at birth: female; Race: white; Year of birth: 1958; Vital status: Dead; Days to death: 1,510 days (4.1 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 51.8 years (18,935 days); WHO CNS grade: Grade IV; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -6 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,161 days (3.2 years); Days to treatment end: 1,245 days (3.4 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,251 days (3.4 years); Days to treatment end: 1,279 days (3.5 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,251 days (3.4 years); Days to treatment end: 1,279 days (3.5 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: recurrence; Age at diagnosis: 55.0 years (20,105 days); Days to diagnosis: 1,170 days (3.2 years).
   Pathology details: Necrosis present: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Temozolomide; Treatment intent type: Maintenance Therapy; Days to treatment start: 14 days; Days to treatment end: 1,153 days (3.2 years); Treatment outcome: Progressive Disease.

Follow-up (3 entries)
- Days to follow up: 1,279 days (3.5 years); Karnofsky performance status: 70.
- Days to follow up: 1,331 days (3.6 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 1,176.

Molecular and laboratory tests
- IDH1 (IHC): Negative; Amino-acid change: R132H.
- IDH1 / IDH2 (Targeted Sequencing): Negative.
- MGMT methylation: Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 56 kg; Height: 161 cm; BMI: 21.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-BROD-0782-C71-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0782-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 4.
